Surgical pathology report (de-identified scan), TCGA case TCGA-CC-A7IG, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site ILSBio, specimen TCGA-CC-A7IG-01A (Primary Tumor).

[page 1 of 5]
TOB APPROVED

Form Revised

Fax:

Clinical Case Report

ICD-0-3
Hepatocellular NOS
8170/3
Site: Liver C22.0
QJ 10/10/13

Informed Consent

I personally informed this patient that a specimen(s) would be collected to be used for research purposes. I reviewed the **RESEARCH SUBJECT INFORMATION AND CONSENT FORM** with the patient and answered any questions the patient had. The patient then signed the consent form as a free and voluntary act. A copy of this informed consent document will be retained at our institution.

Clinical Information

GENERAL INFORMATION				
Date of Birth (mm/dd/yyyy)	Height	Marital Status	Race	Temperature
Gender	Weight		Blood Pressure	Heart Rate
☒ Male ☐ Female			12/8	

HISTORY OF PRESENT ILLNESS
Chief Complaints: Abdominal pain, fever, fatigue.
Symptoms: Weight loss.
Clinical Findings:
Performance Scale (Karnofsky Score): ☐ 100 Asymptomatic ☐ 80-90 Symptomatic but Fully Ambulatory ☒ 60-70 Symptomatic, in bed less than 50% of day ☐ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☐ 20-30 Bed Ridden

CURRENT MEDICATIONS				
Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 2 of 5]
PAST MEDICAL HISTORY			
Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status

OB/GYN HISTORY		
Menopausal Status	Date of First Menses	# of Pregnancies
☐ Pre-menopausal		
☐ Peri-Menopausal	Date of Last Menses	# of Live Births
☐ Post-menopausal		
Birth Control: ☐ Condom ☐ Oral Contraceptive ☐ IUD ☐ Other: _____		☐ Hormone Replacement Therapy: _____

SOCIAL HISTORY				
Occupation:		Environmental Hazards:		
Smoking History				
Current Status	TYPE	Packs/day	Duration	When Quit
☒ YES ☐ NO		1 P/day	(yrs)	1 month ago (yr)
Alcohol Consumption				
Current Status	TYPE	Drinks/day	Duration	When Quit
☒ YES ☐ NO		2 drinks/day	(yrs)	1 year ago (yr)
Drug Use				
Current Status	TYPE	Frequency	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)

FAMILY MEDICAL HISTORY		
Relative	Diagnosis	Age of Diagnosis

LAB DATA						
Test	Result	Date	Test	Result	Date	
HIV	☒ Negative ☐ Positive: _____		CEA	☐ Negative ☐ Positive: _____		
Hep B	☒ Negative ☐ Positive: _____		CA 15-3	☐ Negative ☐ Positive: _____		
Hep C	☒ Negative ☐ Positive: _____		CA 19-9	☐ Negative ☐ Positive: _____		
AFP	☐ Negative ☐ Positive: _____		PSA	☐ Negative ☐ Positive: _____		
Other:	☐ Negative ☐ Positive: _____		Other:	☐ Negative ☐ Positive: _____		
B/T Cell Markers:						

[page 3 of 5]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound		
X-Ray		
CT x	A tumour was found in the right liver	
Endoscopy		
MRI		
Biopsy		

CLINICAL DIAGNOSIS		
Preoperative Clinical Diagnosis		
R. Liver Cancer		
Location of Suspected Involved Lymph Nodes	Location of Suspected Distant Metastasis	
Clinical Staging		Date of Diagnosis
T 2 N 0 M 0 Stage: II		

Treatment Information

SURGICAL TREATMENT		
Procedure		Date of Procedure
Resection of the right liver		
Primary Tumor		
Organ	Detailed Location	Size
Liver Tumor	Right	5 x 4 x 4 cm
Extension of Tumor		
Lymph Nodes		
Description	Location of Lymph Nodes	# of Lymph Nodes
Palpable, Non-Dissected Lymph Nodes		
Dissected Lymph Nodes		
Distant Metastasis		
Organ	Detailed Location	Size
Surgical Staging		
T 2	N 0	M 0
Stage:		II

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 5]
Pathology Form

Specimen Information

Collected by: _____

____ Date: _____ Time

Preserved by: _____

____ Date: _____ Time

SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
4	2	4	2			4	2
Time to LN2		Time to Formalin		Time to LN2			
min		min		min			

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
Liver Tumor	5 x 4 x 4 cm	Rigged	6 cm
Lymph Nodes			
Location	# Examined	# Metastasized	
Distant Metastasis			
Organ	Detailed Location	Size	
Pathological Staging			
pT 2 N 0 M 0 Stage: II			
Notes:			

[page 5 of 5]
IRB APPROVED

Form Revised

Tel:

Fax:

Consolidated Pathology Diagnosis

Histological Pattern											
Cell Distribution			+	-	Structural Pattern			+	-		
Diffuse				X	Streaming						
Mosaic			X		Storiform						
Necrosis			X		Fibrosis						
Lymphocytic Infiltration			X		Palisading						
Vascular Invasion				X	Cystic Degeneration						
Clusterized			X		Bleeding						
Alveolar Formation			X		Myxoid Change						
Indian File				X	Psammoma/Calcification						

Cellular Differentiation																			
Squamous			+	-	Adenomatous			+	-	Sarcomatous			+	-	Lymphomatous			+	-
Squamoid Cell					Glandular cell		X			Round Cell					Large Cell				
Spindle Cell					Cell Stratification		X			Fibroblast					Small Cell				
Keratin					Secretion		X			Osteoblast					RS Cell/RS Like				
Desmosome					Intracyt. Vacuole		X			Lipoblast					Inflam. Cell				
Pearl					Gland formation		X			Myoblast					Plasma Cell				

Cellular Differentiation: ☐ Well ☐ Moderate ☐ Poor

Nuclear Appearance				
Nuclear Atypia:	0	I	II	III
Aniso Nucleosis			X	
Hyperchromatism			X	
Nucleolar Prominent			X	
Multinucleated Giant Cell			X	
Mitotic Activity			X	

Nuclear Grade: ☒ 0 ☐ I ☐ II ☐ III

Final Pathology Report

Histological Diagnosis: Hepatocellular Carcinoma Grade: 2

Comments:

D165% D265% D360% D465% Necrosis 1%

Date

INTEGRATED REPORT OF FINDINGS BY COLLABORATORS AND

ATHOLOGISTS -

riPAA Discrepancy		X

Source: NCI Genomic Data Commons file 5b824c96-dc4f-4a2c-880c-07f8ad4f98f2 (TCGA-CC-A7IG.FF015D7F-02CD-485E-83B6-8C533DE83B2A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).